Somatic mutation profile of tumor specimen TCGA-D9-A4Z3-01A (aliquot TCGA-D9-A4Z3-01A-11D-A25O-08) from TCGA case TCGA-D9-A4Z3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.4 years (26,812 days).
Specimen TCGA-D9-A4Z3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86a00be1-4aa8-4654-8f54-9d1f0a39fd6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A4Z3-10A (Blood Derived Normal), aliquot TCGA-D9-A4Z3-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5c68be3-6a50-40ab-a218-af7d69bb5007

The open-access MAF lists 970 somatic variants for this specimen: 648 protein-altering or splice-affecting, 297 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 600, Silent 297, Nonsense Mutation 26, Splice Site 10, Intron 9, RNA 9, Splice Region 5, Frame Shift Del 3, 3'UTR 3, Frame Shift Ins 3, 3'Flank 2, In Frame Del 1.

Variants (750 of 970; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRF4 | c.1282T>C p.Y428H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66706517; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2M | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV59393485; called by muse, mutect2, varscan2
- ABCB1 | c.2879G>A p.G960E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55958306; called by muse, mutect2, varscan2
- ABCB1 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV55965273; called by muse, mutect2, varscan2
- ABCB1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as COSV55963339; called by muse, mutect2, varscan2
- ABCC1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100579062; called by muse, mutect2, varscan2
- ABCC1 | c.4412C>T p.T1471I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100579068; called by muse, mutect2, varscan2
- ABCC3 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1361744148, COSV53330597; called by muse, mutect2, varscan2
- ABCG8 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV55397468; called by muse, mutect2, varscan2
- AC100868.1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as COSV51850916; called by muse, mutect2, varscan2
- ACE | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); catalogued as COSV52008421, COSV52014015; called by muse, mutect2, varscan2
- ACTRT1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1236531690, COSV64420145; called by muse, mutect2, varscan2
- ADAMTS10 | c.1563C>G p.C521W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV54360219; called by muse, mutect2, varscan2
- ADAMTS4 | c.1596C>G p.C532W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63491393; called by muse, mutect2, varscan2
- ADCY5 | c.2666G>A p.S889N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59204657; called by muse, mutect2, varscan2
- ADGRB1 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs368917249; called by muse, mutect2, varscan2
- ADGRF4 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV51958421; called by muse, mutect2, varscan2
- ADGRG4 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV54968882, COSV99796386; called by muse, mutect2, varscan2
- ADH1B | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59299175; called by muse, mutect2, varscan2
- AFF3 | c.3428C>T p.S1143F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57877184; called by muse, mutect2, varscan2
- AFF4 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs755243717, COSV54800434; called by muse, mutect2
- AGBL1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs772534565, COSV69816145; called by muse, mutect2, varscan2
- AGO2 | c.2491T>C p.S831P | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55053503; called by muse, mutect2, varscan2
- AIFM3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59005005; called by muse, mutect2, varscan2
- AK9 | c.5158C>T p.P1720S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69849326; called by muse, varscan2
- AK9 | c.5081C>T p.P1694L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV69853759; called by muse, varscan2
- ALOX15 | c.314T>A p.V105D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as rs1351542612, COSV53401202; called by muse, mutect2, varscan2
- ALPK3 | c.3370C>T p.P1124S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV51941120, COSV99360237; called by muse, mutect2, varscan2
- AMBRA1 | c.1699C>T p.R567C (on ENST00000458649 / NM_001367468.1; = p.R477C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1214838212, COSV54059400; called by muse, mutect2, varscan2
- AMIGO2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56975787; called by muse, mutect2, varscan2
- ANKRD30A | c.1693T>A p.S565T (on ENST00000611781; = p.S509T on NM_052997.2) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.332); catalogued as COSV64623133; called by muse, mutect2, varscan2
- ANKRD50 | c.1626T>G p.D542E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.508); catalogued as COSV72386400; called by muse, mutect2, varscan2
- ANKS4B | c.1211A>C p.Q404P | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV61140553; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- AP5Z1 | c.2096C>T p.T699I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs772195008, COSV62244113; called by muse, mutect2, varscan2
- APEH | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV56537225; called by muse, mutect2, varscan2
- AQP9 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54971413; called by muse, mutect2, varscan2
- AQR | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs780218820, COSV50058977; called by muse, mutect2, varscan2
- ARFIP1 | c.982A>G p.N328D (on ENST00000353617 / NM_001287432.1; = p.N296D on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV61886514; called by muse, mutect2, varscan2
- ARHGEF17 | c.4328C>G p.P1443R | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV55239158; called by muse, mutect2, varscan2
- ARL9 | c.664G>T p.A222S (on ENST00000640821 / NM_001363794.2; = p.A80S on NM_206919.2) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.396); catalogued as COSV63991613; called by muse, mutect2, varscan2
- ARSL | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV66966103; called by muse, mutect2, varscan2
- ASPH | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57984530; called by muse, mutect2, varscan2
- ASTN1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1386515526, COSV56088677; called by muse, mutect2, varscan2
- ASTN1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV56061735, COSV99922973; called by muse, varscan2
- ASXL2 | c.1495C>A p.Q499K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV55469099; called by muse, mutect2, varscan2
- ASZ1 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV52916933; called by muse, mutect2, varscan2
- ATCAY | c.342C>G p.N114K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV56659824; called by muse, mutect2, varscan2
- ATXN7L2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100149784; called by muse, mutect2, varscan2
- ATXN7L2 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100149786; called by muse, mutect2, varscan2
- AXDND1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV62649971; called by muse, mutect2, varscan2
- BAZ1B | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs781855915, COSV59994521; called by muse, mutect2, varscan2
- BCAS1 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65089975; called by muse, mutect2, varscan2
- BCAS1 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65089981; called by muse, mutect2
- BCL3 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); catalogued as COSV51233892; called by muse, mutect2, varscan2
- BDNF | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.891); catalogued as rs945510399, COSV59239101; called by muse, mutect2, varscan2
- BICC1 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54067470; called by muse, mutect2, varscan2
- BIRC2 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57163357; called by muse, mutect2, varscan2
- BMP2 | c.1038G>C p.Q346H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66579538; called by muse, mutect2, varscan2
- BNC2 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66158773; called by muse, mutect2, varscan2
- BRCA1 | c.3642G>T p.E1214D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs398122675, COSV58798929, COSV58801612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV58789003; called by muse, mutect2, varscan2
- BRINP1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV56303837, COSV56317776; called by muse, mutect2, varscan2
- C1S | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61072559; called by muse, mutect2, varscan2
- C2CD2 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100298069; called by muse, mutect2, varscan2
- C2CD2 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs748046327, COSV100298071, COSV61600185; called by muse, mutect2, varscan2
- C2CD6 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53801229; called by muse, mutect2, varscan2
- C3orf22 | c.216-2A>T p.X72_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100559516; called by muse, mutect2, varscan2
- C4orf17 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV56744569; called by muse, mutect2, varscan2
- C6 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54720422; called by muse, mutect2, varscan2
- C6orf62 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV65291227; called by muse, mutect2, varscan2
- C8orf34 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV61399453; called by muse, mutect2, varscan2
- C9 | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54682243; called by muse, mutect2, varscan2
- CA3 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53409466; called by muse, mutect2, varscan2
- CACNA1H | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265393669, COSV61986302, COSV62006032; called by muse, mutect2, varscan2
- CACNA1H | c.4162G>A p.G1388S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62006041; called by muse, mutect2, varscan2
- CACNA2D3 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1384932664, COSV55587618; called by muse, mutect2
- CAMK1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56540647; called by muse, mutect2, varscan2
- CAMLG | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV51804416; called by muse, mutect2, varscan2
- CAPN9 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777274221, COSV55231800, COSV55240471; called by muse, mutect2, varscan2
- CAPZA3 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56851738; called by muse, mutect2, varscan2
- CARMIL3 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1480239369, COSV57728721; called by muse, mutect2, varscan2
- CASS4 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64388740; called by muse, mutect2, varscan2
- CBLIF | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57240646; called by muse, mutect2, varscan2
- CCDC144A | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs776066736, COSV60702506; called by muse, mutect2
- CCDC62 | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV53437624; called by muse, mutect2, varscan2
- CCDC63 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV57531675; called by muse, mutect2, varscan2
- CCDC70 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs746617980, COSV54431155; called by muse, mutect2, varscan2
- CCDC81 | c.1010C>T p.S337F (on ENST00000445632 / NM_001156474.2; = p.S247F on NM_021827.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53576695; called by muse, mutect2, varscan2
- CCNB3 | c.3810G>A p.R1270= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as rs782405123, COSV52080665; called by muse, mutect2
- CD276 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV59206020; called by muse, mutect2, varscan2
- CD33 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV51800256; called by muse, mutect2
- CD33 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51805473; called by muse, mutect2, varscan2
- CDC42BPB | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932105669, COSV63477202; called by muse, mutect2
- CDH23 | c.4333G>A p.D1445N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV56493946; called by muse, mutect2, varscan2
- CDHR2 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV56146242; called by muse, mutect2, varscan2
- CDHR2 | c.2876G>A p.G959E | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV56146252; called by muse, mutect2, varscan2
- CDYL2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs924856145, COSV101629530; called by muse, mutect2, varscan2
- CEBPE | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as COSV52830880, COSV99247345; called by muse, mutect2, varscan2
- CEP170B | c.3978G>C p.E1326D (on ENST00000453495; = p.E1255D on NM_015005.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV52045716; called by muse, mutect2, varscan2
- CERKL | c.1346+2T>C p.X449_splice (on ENST00000339098 / NM_001030311.2; = p.X423_splice on NM_201548.5) | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59214697; called by muse, mutect2
- CERS3 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV52575680, COSV99431372; called by muse, mutect2, varscan2
- CFAP46 | c.6536G>A p.R2179K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV54160628; called by muse, mutect2, varscan2
- CHAT | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as rs774834313, COSV60334614; called by muse, mutect2, varscan2
- CHD6 | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64688994; called by muse, mutect2, varscan2
- CHRDL2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733655; called by muse, mutect2
- CHRDL2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765250083, COSV55222629; called by muse, mutect2
- CLCA1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99322103; called by muse, mutect2, varscan2
- CLDN9 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs766960811, COSV60911599; called by muse, mutect2, varscan2
- CLEC17A | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60430143; called by muse, mutect2, varscan2
- CLEC4C | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV63582527; called by muse, mutect2, varscan2
- CLEC4F | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs782010298, COSV55481951; called by muse, mutect2, varscan2
- CNTNAP2 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV100670050, COSV62267647; called by muse, mutect2, varscan2
- COL17A1 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62229885; called by muse, mutect2, varscan2
- COL28A1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101258444, COSV68082239; called by muse, mutect2, varscan2
- COL28A1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101258446; called by muse, mutect2, varscan2
- COL4A4 | c.4835G>A p.G1612E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61630398; called by muse, mutect2, varscan2
- COL4A4 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637273; called by muse, mutect2
- COL5A3 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53420490; called by muse, mutect2, varscan2
- COL6A1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.25); catalogued as rs1235742792, COSV100720070; called by muse, mutect2
- CP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV52834715; called by muse, mutect2, varscan2
- CPA1 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50576804; called by muse, mutect2, varscan2
- CPNE7 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 24/29 reads (83%) | catalogued as rs746412840, COSV52016974; called by muse, mutect2, varscan2
- CPT1C | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV54922119; called by muse, mutect2, varscan2
- CR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65508854; called by muse, mutect2, varscan2
- CRLF3 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV60837692; called by muse, mutect2, varscan2
- CSF2RB | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.203); catalogued as COSV99453543; called by muse, mutect2, varscan2
- CSMD1 | c.3332G>A p.G1111E (on ENST00000520002; = p.G1110E on NM_033225.6) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1563296664, COSV59360550; called by muse, mutect2, varscan2
- CSMD2 | c.8422G>A p.G2808R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53970902; called by muse, mutect2, varscan2
- CTDP1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50009922; called by muse, mutect2, varscan2
- CTNNA2 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs762691048, COSV58185979; called by muse, mutect2, varscan2
- CTPS2 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63724580; called by muse, mutect2, varscan2
- CTR9 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV63729837; called by muse, mutect2, varscan2
- CTSE | c.869C>T p.S290F (on ENST00000360218; = p.S285F on NM_001910.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733570; called by muse, mutect2, varscan2
- CYP1A1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65698380; called by muse, mutect2, varscan2
- CYP4F22 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV54112387; called by muse, mutect2, varscan2
- CYRIA | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV62867501; called by muse, mutect2
- DAPK1 | c.2314G>A p.G772R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs374989008; called by muse, mutect2, varscan2
- DCC | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59141526; called by muse, mutect2, varscan2
- DENND3 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV52807620; called by muse, mutect2, varscan2
- DHRS4 | c.532-1G>A p.X178_splice | Splice Site (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100365822; called by muse, mutect2, varscan2
- DHRS4 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as rs1566477301, COSV100365825; called by muse, mutect2, varscan2
- DHX29 | c.3868A>G p.I1290V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.362); catalogued as COSV52422924; called by muse, mutect2, varscan2
- DISP3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1319873156, COSV53825140, COSV99609035; called by muse, mutect2, varscan2
- DLG5 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV64950296; called by muse, mutect2, varscan2
- DNAH10 | c.2983C>T p.R995C (on ENST00000409039; = p.R934C on NM_207437.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757691040, COSV68989857; called by muse, mutect2, varscan2
- DNAH5 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54256658; called by muse, mutect2, varscan2
- DNAH9 | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs770487783, COSV52350594, COSV52380445; called by muse, mutect2, varscan2
- DNAI2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV56763015; called by muse, mutect2, varscan2
- DNAJC3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as rs1317503503, COSV65133346; called by muse, mutect2, varscan2
- DNM3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754268755, COSV62468632; called by muse, mutect2, varscan2
- DOCK7 | c.6295C>A p.H2099N (on ENST00000635253 / NM_001367561.1; = p.H2068N on NM_033407.3) | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52023606; called by muse, mutect2, varscan2
- DSCAM | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68037872; called by muse, mutect2, varscan2
- DSE | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100528339, COSV59067864; called by muse, mutect2, varscan2
- DYDC2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1317291182, COSV55472096; called by muse, mutect2, varscan2
- DYNAP | c.256C>T p.L86F (on ENST00000321600; = p.L60F on NM_173629.3) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs757753272, COSV58667195; called by muse, mutect2, varscan2
- DYRK3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as rs1553420492, COSV65608259; called by muse, mutect2, varscan2
- DYSF | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV50455273; called by muse, mutect2, varscan2
- DZIP1L | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.174); catalogued as rs1276163556, COSV59523883; called by muse, mutect2, varscan2
- EBF3 | c.910G>A p.E304K (on ENST00000355311 / NM_001375392.1; = p.E295K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV62482718; called by muse, mutect2, varscan2
- ECT2 | c.1940C>G p.A647G (on ENST00000392692 / NM_001349098.2; = p.A616G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51695125; called by muse, mutect2, varscan2
- EED | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54558894; called by muse, mutect2, varscan2
- EFCAB6 | c.2915C>G p.A972G | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV53074157; called by muse, mutect2, varscan2
- EFCAB7 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64315524; called by muse, mutect2, varscan2
- ELFN2 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68744451; called by muse, mutect2, varscan2
- ELOA2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV55309938; called by muse, mutect2, varscan2
- EMCN | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56460175, COSV56465117; called by muse, mutect2, varscan2
- EMILIN2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs376456618; called by muse, mutect2, varscan2
- ENPP3 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62957230; called by muse, mutect2, varscan2
- ENTPD1 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.25); catalogued as rs1566233337, COSV64604799; called by muse, mutect2, varscan2
- EPB41L2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV61359572; called by muse, mutect2, varscan2
- EPB41L5 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55358816; called by muse, mutect2, varscan2
- EPHX2 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66846291; called by muse, mutect2, varscan2
- ERBB4 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV61482936; called by muse, mutect2, varscan2
- ERBB4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV53596379; called by muse, mutect2, varscan2
- ERCC6 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63394963; called by muse, mutect2, varscan2
- EXOC8 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99149611; called by muse, mutect2, varscan2
- FAM171A1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1231110791, COSV65320754; called by muse, mutect2, varscan2
- FAM171B | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.686); catalogued as COSV59009676; called by muse, mutect2, varscan2
- FAM47A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.344); catalogued as rs750698635, COSV60496289; called by muse, mutect2, varscan2
- FAM47B | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV61457150; called by muse, mutect2, varscan2
- FAM47B | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV61452791; called by muse, mutect2, varscan2
- FAM71D | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61294731; called by muse, mutect2, varscan2
- FAM76A | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV50550101; called by muse, mutect2, varscan2
- FAM83C | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.027); catalogued as rs1568634709, COSV65584758; called by muse, mutect2, varscan2
- FAM83G | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV58762825; called by muse, mutect2, varscan2
- FAM86B1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1010739092, COSV100392164; called by muse, mutect2, varscan2
- FAS | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV58240266; called by muse, mutect2, varscan2
- FASN | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV60762132; called by muse, mutect2, varscan2
- FBF1 | c.1916C>T p.S639L (on ENST00000586717; = p.S653L on NM_001319193.1) | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs200342777, COSV59865106; called by muse, mutect2, varscan2
- FBXO40 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1441822615, COSV57524059; called by muse, mutect2, varscan2
- FBXO43 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV71055706; called by muse, mutect2, varscan2
- FCRL1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV63827931; called by muse, mutect2, varscan2
- FGF7 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1453185788, COSV51067845; called by muse, mutect2, varscan2
- FIZ1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV55609470; called by muse, mutect2, varscan2
- FKBP9 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54234218, COSV54235522; called by muse, mutect2
- FLNB | c.2593C>G p.P865A | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55898557; called by muse, mutect2, varscan2
- FMNL1 | c.3020G>A p.W1007* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100056319; called by muse, mutect2, varscan2
- FMNL1 | c.3021G>A p.W1007* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs1309933440, COSV58957082; called by muse, mutect2, varscan2
- FNDC1 | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs143447403, COSV51940507; called by muse, mutect2, varscan2
- FOXG1 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV57400014; called by muse, mutect2, varscan2
- FOXJ3 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100691622; called by muse, mutect2, varscan2
- FOXJ3 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100691624; called by muse, mutect2, varscan2
- FRMPD1 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66703113, COSV66703616; called by muse, mutect2, varscan2
- FRS2 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs777566936, COSV54723245; called by muse, mutect2, varscan2
- FSCB | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100469217, COSV61216583; called by muse, mutect2, varscan2
- FSIP1 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs375568122; called by muse, mutect2, varscan2
- FSIP2 | c.18674C>T p.S6225F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100555053, COSV58101976; called by muse, mutect2, varscan2
- G6PC | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53833164; called by muse, mutect2, varscan2
- G6PC2 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs768200400, COSV56373755; called by muse, mutect2, varscan2
- GABRA1 | c.1199T>A p.V400D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV50123187; called by muse, mutect2
- GAS2L1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs765327110, COSV53332173; called by muse, mutect2, varscan2
- GDF5 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV65503869; called by muse, mutect2, varscan2
- GFRAL | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61236292; called by muse, mutect2, varscan2
- GK2 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150499437, COSV62627775; called by muse, mutect2, varscan2
- GLUL | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs750433606, COSV59383588; called by muse, mutect2, varscan2
- GLYATL1 | c.705G>A p.M235I (on ENST00000317391 / NM_001354699.1; = p.M266I on NM_080661.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs144071638; called by muse, mutect2, varscan2
- GPC5 | c.1563G>A p.W521* | Nonsense Mutation (SNP) | VAF 53/62 reads (85%) | catalogued as rs763208703, COSV65600001; called by muse, mutect2, varscan2
- GPER1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as COSV52470401; called by muse, mutect2
- GPR50 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs374353730, COSV54439920; called by muse, mutect2, varscan2
- GRHL3 | c.439C>T p.P147S (on ENST00000350501 / NM_198174.3; = p.P152S on NM_021180.3) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs778111145, COSV52571584; called by muse, mutect2, varscan2
- GRIA1 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as COSV53627714; called by muse, mutect2
- GRID2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as COSV56192103; called by muse, mutect2, varscan2
- GRIK3 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66147985; called by muse, mutect2, varscan2
- GRM1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51371241; called by muse, mutect2, varscan2
- GRM6 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV51436029; called by muse, mutect2, varscan2
- GRM7 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63175450; called by muse, mutect2, varscan2
- GRM8 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs267601269, COSV58808223; called by muse, mutect2, varscan2
- GSDMA | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.207); catalogued as rs1271993391, COSV52860107; called by muse, mutect2, varscan2
- GSTCD | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV64736116; called by muse, mutect2, varscan2
- GZF1 | c.1978A>T p.M660L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57638987; called by muse, mutect2, varscan2
- HDAC4 | c.2245C>T p.L749F | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61876971; called by muse, mutect2, varscan2
- HDAC9 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67786626; called by muse, mutect2, varscan2
- HDC | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV51084446; called by muse, mutect2, varscan2
- HEPHL1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV59889485, COSV59897318; called by muse, mutect2, varscan2
- HIF3A | c.1691C>T p.P564L (on ENST00000377670 / NM_152795.4; = p.P495L on NM_022462.4) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52197605; called by muse, mutect2, varscan2
- HMGCR | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV55318372; called by muse, mutect2, varscan2
- HNRNPLL | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55369665; called by muse, mutect2, varscan2
- HRG | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs370685538; called by muse, mutect2, varscan2
- HRNR | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs376682455; called by muse, mutect2, varscan2
- HSCB | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53262837; called by muse, mutect2, varscan2
- IFNA7 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV53332497, COSV99497445; called by muse, mutect2, varscan2
- IFNW1 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66522308, COSV66522532; called by muse, mutect2, varscan2
- IFT122 | c.2215C>T p.L739F (on ENST00000348417 / NM_052989.3; = p.L680F on NM_018262.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs763332787, COSV99959014; called by muse, mutect2, varscan2
- IGHM | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs782406602; called by muse, mutect2, varscan2
- IGKV2D-24 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1465664825; called by muse, mutect2, varscan2
- IGSF9 | c.1276G>A p.E426K (on ENST00000368094 / NM_001135050.2; = p.E410K on NM_020789.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV63638710; called by muse, mutect2, varscan2
- IKBKB | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV60600190; called by muse, mutect2, varscan2
- IL1A | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as COSV54520600; called by muse, mutect2, varscan2
- INPPL1 | c.3201dup p.S1068Qfs*17 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | catalogued as COSV53354954; called by mutect2, pindel, varscan2
- INS-IGF2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV51748621; called by muse, mutect2, varscan2
- INTS8 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.623); catalogued as rs1239807779, COSV100569208; called by muse, mutect2, varscan2
- IRAG1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV70213204; called by muse, mutect2, varscan2
- IRAK2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV56536373; called by muse, mutect2, varscan2
- IRAK2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV56529218; called by muse, mutect2, varscan2
- ITGA2B | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV52233902; called by muse, mutect2, varscan2
- ITGAL | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63319887, COSV63324761; called by muse, mutect2, varscan2
- ITIH5 | c.113A>C p.Q38P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56916787; called by muse, mutect2, varscan2
- ITPKB | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV55270977; called by mutect2, varscan2
- ITPRID1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV60084270, COSV60084903; called by muse, mutect2, varscan2
- JMJD7 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | catalogued as rs1355566886, COSV100583795; called by muse, mutect2, varscan2
- KANSL1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs535224667, COSV52275002; called by muse, mutect2, varscan2
- KCNB2 | c.582C>T p.I194= | Splice Region (SNP) | VAF 55/192 reads (29%) | catalogued as COSV73049584; called by muse, mutect2, varscan2
- KCNJ11 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60595738; called by muse, mutect2, varscan2
- KCNV1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs866800552, COSV52084745; called by muse, mutect2, varscan2
- KCTD21 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as COSV60741267; called by muse, mutect2, varscan2
- KERA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as COSV57131005, COSV99899258; called by muse, mutect2, varscan2
- KHDRBS1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs1160997272, COSV56983972; called by muse, mutect2, varscan2
- KIF25 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252580329, COSV63029200; called by muse, mutect2, varscan2
- KRT71 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57293413; called by muse, mutect2, varscan2
- KRT81 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV59811617; called by muse, mutect2, varscan2
- LAMA1 | c.7885C>T p.P2629S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866137763, COSV67545244; called by muse, mutect2, varscan2
- LAMC2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs374263073; called by muse, mutect2, varscan2
- LEPR | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1051707790, COSV62748180; called by muse, mutect2, varscan2
- LIFR | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54701489; called by muse, mutect2, varscan2
- LILRA2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV52196708; called by muse, mutect2, varscan2
- LILRA2 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV52190728; called by muse, mutect2, varscan2
- LIN7A | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54021762; called by muse, mutect2, varscan2
- LINGO1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV62438539, COSV62438820; called by muse, mutect2, varscan2
- LRFN1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs774000890, COSV99952800; called by muse, varscan2
- LRP1 | c.10775G>A p.W3592* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54528437; called by muse, mutect2
- LRP1B | c.4757G>A p.G1586E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67281453; called by muse, mutect2, varscan2
- LRP1B | c.3880G>A p.D1294N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67281457; called by muse, mutect2, varscan2
- LRP6 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53795802; called by muse, mutect2, varscan2
- LRRC32 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as rs868735827, COSV52633501; called by muse, mutect2, varscan2
- LRRC4C | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs867956688, COSV53426374, COSV53432590; called by muse, mutect2, varscan2
- LRRC61 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs772666241, COSV56230999, COSV99784519, COSV99784586; called by muse, varscan2
- LRRC61 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99784587; called by muse, varscan2
- LRRC74A | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.402); catalogued as rs376088587; called by muse, mutect2, varscan2
- LSG1 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54573040; called by muse, mutect2, varscan2
- MAG | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.065); catalogued as rs1308767317, COSV62703332; called by muse, mutect2
- MAGEA10 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 77/105 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs866347309, COSV54886324; called by muse, mutect2, varscan2
- MAGEA11 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV100290435; called by muse, mutect2, varscan2
- MAGEA11 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV100290437; called by muse, mutect2, varscan2
- MAGEA3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as rs1475020079, COSV100939022; called by muse, mutect2, varscan2
- MALL | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV55601529; called by muse, mutect2, varscan2
- MAN2A1 | c.2513T>G p.V838G | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54859633; called by muse, mutect2, varscan2
- MAP4K2 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53649440; called by muse, mutect2, varscan2
- MATN4 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | PolyPhen benign (0); catalogued as COSV59216138; called by muse, mutect2
- MCF2 | c.1806G>A p.W602* | Nonsense Mutation (SNP) | VAF 60/84 reads (71%) | catalogued as rs753865095, COSV58496348; called by muse, mutect2, varscan2
- MECOM | c.490G>A p.E164K (on ENST00000468789 / NM_001105078.4; = p.E352K on NM_004991.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV52976744; called by muse, mutect2, varscan2
- MECOM | c.235G>A p.E79K (on ENST00000468789 / NM_001105078.4; = p.E267K on NM_004991.4) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52976762; called by muse, mutect2, varscan2
- MFSD8 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV56553244; called by muse, mutect2, varscan2
- MGAM | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs368035457; called by muse, mutect2, varscan2
- MGAM | c.4656G>A p.T1552= | Splice Region (SNP) | VAF 14/46 reads (30%) | catalogued as rs775637202, COSV72075157, COSV72075740; called by muse, mutect2, varscan2
- MGAT4C | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59838534; called by muse, mutect2, varscan2
- MIDN | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV56297323; called by muse, mutect2, varscan2
- MLXIPL | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV57670871; called by muse, mutect2, varscan2
- MMEL1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as COSV56526952; called by muse, mutect2, varscan2
- MMP28 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1555604842; called by muse, mutect2, varscan2
- MMP3 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV55405464; called by muse, mutect2, varscan2
- MOG | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65321984; called by muse, mutect2, varscan2
- MRGPRX1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as COSV57110061; called by muse, mutect2, varscan2
- MROH7 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV59879040; called by muse, mutect2, varscan2
- MRPL39 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV56262421; called by muse, mutect2, varscan2
- MSL2 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99386763; called by muse, mutect2, varscan2
- MSL2 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99386764; called by muse, mutect2, varscan2
- MUC16 | c.35891C>T p.P11964L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV67499268; called by muse, mutect2, varscan2
- MUC16 | c.32764C>T p.P10922S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.245); catalogued as COSV67461188; called by muse, mutect2, varscan2
- MUC16 | c.22880C>A p.P7627H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV67499281; called by muse, mutect2, varscan2
- MUC16 | c.22405G>A p.E7469K | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as COSV67442819; called by muse, mutect2, varscan2
- MUC3A | c.8395C>T p.P2799S | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV100114286, COSV100115128; called by muse, mutect2
- MUC3A | c.8396C>T p.P2799L | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV100114288; called by muse, mutect2
- MXRA5 | c.5107G>A p.G1703R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV54253192; called by muse, varscan2
- MXRA5 | c.5041C>T p.P1681S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.68); catalogued as COSV54253212; called by muse, varscan2
- MXRA5 | c.3982G>A p.D1328N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54238211; called by muse, mutect2, varscan2
- MYCBPAP | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.185); catalogued as rs375760319; called by muse, mutect2, varscan2
- MYCT1 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV65892111; called by muse, mutect2, varscan2
- MYH15 | c.4657C>A p.Q1553K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV56321359; called by muse, mutect2, varscan2
- MYH15 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.593); catalogued as COSV56313815; called by muse, mutect2, varscan2
- MYH2 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1459718999, COSV55450299; called by muse, mutect2, varscan2
- MYH4 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55121327; called by muse, mutect2, varscan2
- MYH4 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99700737; called by muse, mutect2, varscan2
- MYH6 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62455136; called by muse, mutect2
- MYH7 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV62521010; called by muse, mutect2, varscan2
- MYH7B | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52682952; called by muse, mutect2, varscan2
- MYLK3 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67367299; called by muse, mutect2, varscan2
- MYO3B | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs746744711, COSV58711463; called by muse, mutect2, varscan2
- MYOM2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.284); catalogued as rs564509220, COSV50789846; called by muse, mutect2, varscan2
- MYOZ3 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV51741302; called by muse, mutect2, varscan2
- NCAPH2 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53220418; called by muse, mutect2, varscan2
- NCF1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99194259; called by muse, mutect2, varscan2
- NDST4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs767236676, COSV52123386; called by muse, mutect2, varscan2
- NDST4 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV99995989; called by muse, mutect2, varscan2
- NEBL | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV101009074, COSV65806327; called by muse, mutect2, varscan2
- NEK9 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.037); catalogued as COSV53130084, COSV53133832; called by muse, mutect2, varscan2
- NFATC2 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 17/27 reads (63%) | catalogued as COSV101043857; called by muse, mutect2, varscan2
- NFE2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56457651; called by muse, mutect2, varscan2
- NGFR | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as rs377497410; called by muse, mutect2, varscan2
- NIBAN1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762803465, COSV62288287; called by muse, mutect2, varscan2
- NMUR1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as rs141278960; called by muse, mutect2, varscan2
- NOS2 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.804); catalogued as COSV58222477, COSV58227999; called by muse, mutect2, varscan2
- NOVA1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.04); catalogued as COSV99947022; called by muse, mutect2, varscan2
- NPHP3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1419206602, COSV100447476, COSV58130992; called by muse, mutect2, varscan2
- NPM2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs773383353, COSV57076659, COSV99235678; called by muse, mutect2, varscan2
- NSD1 | c.3265G>A p.D1089N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV61786124; called by muse, mutect2, varscan2
- NUAK2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs199544834, COSV65681729; called by muse, mutect2, varscan2
- NWD1 | c.2295T>G p.I765M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV60353248; called by muse, mutect2, varscan2
- NYAP2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56018137; called by muse, mutect2, varscan2
- OAS2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200216272; called by muse, mutect2, varscan2
- OAZ3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1254587779, COSV58620002; called by muse, mutect2, varscan2
- OGN | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 16/20 reads (80%) | catalogued as COSV52762197; called by muse, mutect2, varscan2
- ONECUT1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs746910544, COSV59948032; called by muse, mutect2, varscan2
- OPLAH | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1408742789, COSV101470746; called by muse, mutect2, varscan2
- OR10J1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs748637321, COSV71129549; called by muse, mutect2, varscan2
- OR10K1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746569386, COSV56870742, COSV99193195; called by muse, mutect2, varscan2
- OR1N1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59197039; called by muse, mutect2, varscan2
- OR2T33 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58818283; called by muse, mutect2, varscan2
- OR2T6 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV63216515; called by muse, mutect2
- OR3A3 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752038909, COSV52167252, COSV52168343; called by muse, mutect2, varscan2
- OR4K1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs755426984, COSV53459544, COSV99579075; called by muse, mutect2, varscan2
- OR52A1 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61093075; called by muse, mutect2, varscan2
- OR52E4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs768164155, COSV57623964, COSV57624022; called by muse, mutect2
- OR5B2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs773028151, COSV56909938; called by muse, mutect2, varscan2
- OR5D13 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV62334602; called by muse, mutect2, varscan2
- OR6X1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60009719; called by muse, mutect2, varscan2
- OSBPL7 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV50117076; called by muse, mutect2, varscan2
- OSCP1 | c.712G>A p.V238I (on ENST00000356637 / NM_001330493.1; = p.V228I on NM_145047.5) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV52488633; called by muse, mutect2, varscan2
- OTULIN | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.668); catalogued as COSV52507412; called by muse, mutect2, varscan2
- P2RX4 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV58742943; called by muse, mutect2, varscan2
- P2RX5 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs750820489, COSV56594193; called by muse, mutect2, varscan2
- PAH | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs865899394, CM1314632, COSV61020970; called by muse, mutect2, varscan2
- PAIP2 | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV54527002; called by muse, mutect2, varscan2
- PANX3 | c.181+1G>A p.X61_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52511993, COSV52514052; called by muse, mutect2, varscan2
- PAPLN | c.1744C>G p.P582A (on ENST00000554301; = p.P555A on NM_173462.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV99389378; called by muse, mutect2, varscan2
- PAPPA2 | c.5035C>T p.P1679S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV62790645, COSV62802420, COSV62813784; called by muse, mutect2, varscan2
- PARP12 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV54935729; called by muse, mutect2, varscan2
- PCDHA1 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974328; called by muse, mutect2, varscan2
- PCDHA13 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.653); catalogued as COSV56484666; called by muse, mutect2, varscan2
- PCDHA9 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65325501; called by muse, mutect2, varscan2
- PCDHB15 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV51427025; called by muse, mutect2, varscan2
- PCDHB7 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1554279989, COSV50827318; called by muse, mutect2, varscan2
- PCLO | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV61673479; called by muse, mutect2, varscan2
- PCNX1 | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.056); catalogued as COSV53103450; called by muse, mutect2, varscan2
- PCSK5 | c.4636G>A p.G1546R | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1276000901, COSV70453357; called by muse, mutect2
- PDE7B | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776783458, COSV57510148; called by muse, mutect2, varscan2
- PDIA5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755947481, COSV60249469; called by muse, mutect2, varscan2
- PDIA5 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.458); catalogued as COSV60253087; called by muse, mutect2, varscan2
- PDZK1IP1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53744758; called by muse, mutect2, varscan2
- PEG3 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99688115; called by muse, mutect2, varscan2
- PHACTR4 | c.572C>T p.S191F (on ENST00000373839 / NM_001350159.2; = p.S201F on NM_023923.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.259); catalogued as rs569659101, COSV65784695; called by muse, mutect2, varscan2
- PICALM | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV62672105; called by muse, mutect2, varscan2
- PIGR | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as rs137917999; called by muse, varscan2
- PKHD1L1 | c.4643C>T p.T1548I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs771127653, COSV101005804, COSV65748498; called by muse, mutect2
- PKP1 | c.1157G>A p.W386* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1463014197, COSV55826054; called by muse, mutect2, varscan2
- PKP2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as rs759377911, COSV50752588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G2E | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64291046; called by muse, mutect2, varscan2
- PLA2G4D | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 88/138 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs150830051; called by muse, mutect2, varscan2
- PLAG1 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57616182; called by muse, mutect2, varscan2
- PLCB1 | c.2414-1G>A p.X805_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100570131; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746073648, COSV60610978, COSV60618210; called by muse, mutect2
- PLEKHA4 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54366791; called by muse, mutect2, varscan2
- PLEKHA7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV63051801; called by muse, mutect2, varscan2
- PLK3 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59501396; called by muse, mutect2, varscan2
- PLPPR4 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100926744; called by muse, mutect2, varscan2
- PLXNA4 | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58164527; called by muse, mutect2, varscan2
- PMEPA1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55696928; called by muse, mutect2, varscan2
- POLQ | c.4693C>T p.Q1565* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV51762969; called by muse, mutect2, varscan2
- POLR2B | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100107953; called by muse, mutect2, varscan2
- POLR2B | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100107954; called by muse, mutect2, varscan2
- POLR2I | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99387472; called by muse, mutect2, varscan2
- POLR2I | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.601); catalogued as COSV99387473; called by muse, mutect2, varscan2
- POMC | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs775159616, COSV53035874; called by muse, mutect2, varscan2
- PPA1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100949873; called by muse, mutect2, varscan2
- PPA1 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100949876; called by muse, mutect2, varscan2
- PPP1R10 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV64740646; called by muse, mutect2, varscan2
- PPP1R16A | c.261C>T p.V87= | Splice Region (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99477514; called by muse, mutect2
- PPP1R16B | c.334A>C p.N112H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55385967; called by muse, mutect2, varscan2
- PPP1R3A | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV52882748; called by muse, varscan2
- PQBP1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as COSV54432010; called by muse, varscan2
- PRDM9 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs765775694, COSV99690137; called by muse, mutect2, varscan2
- PRDM9 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV57003307; called by muse, mutect2, varscan2
- PRKCE | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077323; called by muse, mutect2, varscan2
- PSD3 | c.22-1G>A p.X8_splice | Splice Site (SNP) | VAF 34/76 reads (45%) | catalogued as COSV58981112; called by muse, mutect2, varscan2
- PSG7 | c.484A>C p.T162P | Missense Mutation (SNP) | VAF 123/198 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as COSV68446895; called by muse, mutect2, varscan2
- PSME2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53757894; called by muse, varscan2
- PSME4 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs1396558192, COSV101122612, COSV66368299; called by muse, mutect2, varscan2
- PTBP1 | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62461137, COSV62462056; called by muse, mutect2, varscan2
- PTF1A | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV64734818; called by muse, mutect2, varscan2
- PTGFR | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66116976; called by muse, mutect2, varscan2
- PTPRG | c.3146G>A p.R1049Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs150212631, CM155431; called by muse, mutect2, varscan2
- PTPRJ | c.2758G>T p.G920W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69254994; called by muse, mutect2, varscan2
- PTPRT | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as COSV100625568, COSV62028610; called by muse, mutect2, varscan2
- PTPRZ1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV66432680, COSV66446883; called by muse, mutect2, varscan2
- PTPRZ1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV66446890; called by muse, mutect2, varscan2
- PVR | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV51824678, COSV51825081; called by muse, mutect2
- PXDNL | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs1409911593, COSV62485097, COSV62494635; called by muse, mutect2, varscan2
- PXDNL | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV100681320, COSV62479382; called by muse, mutect2, varscan2
- QRSL1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs896823538, COSV64687443; called by muse, mutect2, varscan2
- RAET1E | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV100593471, COSV61723324; called by muse, mutect2, varscan2
- RAG1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55028929; called by muse, mutect2, varscan2
- RALGAPA1 | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.462); catalogued as COSV51899208; called by muse, mutect2, varscan2
- RANBP1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV57710767; called by muse, mutect2, varscan2
- RAP1A | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs925184298, COSV62729515; called by muse, mutect2, varscan2
- RARRES2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV56232219; called by muse, mutect2
- RASEF | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64586194; called by muse, mutect2, varscan2
- RASSF6 | c.418C>T p.R140C (on ENST00000342081 / NM_201431.2; = p.R108C on NM_177532.5) | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs142555062; called by muse, mutect2, varscan2
- RASSF9 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100771287; called by muse, mutect2, varscan2
- RBBP6 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); catalogued as COSV60508973; called by muse, mutect2, varscan2
- RBM42 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV52899486; called by muse, mutect2, varscan2
- RDH8 | c.559G>A p.E187K (on ENST00000651512; = p.E167K on NM_015725.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755753285, COSV50674103; called by muse, mutect2, varscan2
- RER1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV60384615; called by muse, mutect2, varscan2
- REXO4 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1334117502, COSV63023250, COSV63023490; called by muse, mutect2, varscan2
- RFC3 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 105/118 reads (89%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101197805; called by muse, mutect2, varscan2
- RFC3 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV101197806; called by muse, mutect2, varscan2
- RGS3 | c.3145C>T p.P1049S (on ENST00000350696 / NM_001282923.2; = p.P768S on NM_130795.4) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs769286786, COSV100636640; called by muse, mutect2, varscan2
- RGS3 | c.3146C>T p.P1049L (on ENST00000350696 / NM_001282923.2; = p.P768L on NM_130795.4) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs772969488, COSV100636641; called by muse, mutect2, varscan2
- RGS8 | c.103C>T p.P35S (on ENST00000367556 / NM_001369564.2; = p.P53S on NM_033345.3) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV51121002; called by muse, mutect2, varscan2
- RIMS2 | c.323G>C p.C108S | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68501699, COSV68503237; called by muse, mutect2, varscan2
- RLIM | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60329484; called by muse, mutect2, varscan2
- RP1 | c.4606C>A p.P1536T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV55128568; called by muse, mutect2, varscan2
- RPS6KA5 | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs577750321, COSV56226464; called by muse, mutect2, varscan2
- RWDD1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV63973103; called by muse, mutect2, varscan2
- S100A8 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64198296; called by muse, mutect2, varscan2
- SACS | c.1979A>G p.Y660C | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66538047; called by muse, mutect2, varscan2
- SAMD7 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV59417629; called by muse, mutect2, varscan2
- SAP130 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as rs750756873, COSV52102945; called by muse, mutect2, varscan2
- SCLT1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55411061, COSV55413482; called by muse, mutect2, varscan2
- SCRN1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54134802; called by muse, mutect2, varscan2
- SDF4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs779391857, COSV55422087; called by muse, mutect2, varscan2
- SEC24D | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV99755703; called by muse, mutect2, varscan2
- SERPINB13 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs138290904; called by muse, mutect2, varscan2
- SERPINB4 | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV61986400; called by muse, mutect2, varscan2
- SETD2 | c.7138C>G p.P2380A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100340067, COSV57431643, COSV57454087; called by muse, mutect2, varscan2
- SETD7 | c.921-2A>G p.X307_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99918416; called by muse, mutect2, varscan2
- SFMBT1 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV56257994; called by muse, mutect2, varscan2
- SFTPD | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV64853847; called by muse, mutect2, varscan2
- SGMS1 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100693252; called by muse, mutect2, varscan2
- SHISA2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV60112142; called by muse, mutect2, varscan2
- SIMC1 | c.1699G>A p.V567I (on ENST00000443967 / NM_001308196.1; = p.V152I on NM_198567.5) | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV57908211; called by muse, mutect2, varscan2
- SKP1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV60436616; called by muse, mutect2, varscan2
- SLC17A6 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54142580; called by muse, mutect2, varscan2
- SLC1A6 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693549; called by muse, mutect2, varscan2
- SLC22A13 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61290523; called by muse, mutect2, varscan2
- SLC22A9 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54169839; called by muse, mutect2, varscan2
- SLC23A1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV62297793; called by muse, mutect2, varscan2
- SLC24A3 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284201158, COSV60135188; called by muse, mutect2
- SLC30A9 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52554581, COSV52560187; called by muse, varscan2
- SLC35C2 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV54757073, COSV54758713; called by muse, mutect2, varscan2
- SLC35G5 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs536975881, COSV99644109; called by muse, mutect2, varscan2
- SLC39A12 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs782401970, COSV66202471; called by muse, mutect2, varscan2
- SLC39A4 | c.320C>T p.P107L (on ENST00000301305 / NM_001374839.1; = p.P82L on NM_017767.3) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52781840; called by muse, mutect2, varscan2
- SLC44A5 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63775851; called by muse, mutect2, varscan2
- SLC5A12 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV68448104; called by muse, mutect2
- SLC6A17 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs895234152, COSV100521271, COSV58997371; called by muse, mutect2, varscan2
- SLC9B1 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56476362; called by muse, mutect2
- SLCO1B3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53947837; called by muse, mutect2, varscan2
- SLIT2 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56570425; called by muse, mutect2, varscan2
- SLIT3 | c.2236C>T p.L746F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1407033312, COSV100266329; called by muse, mutect2, varscan2
- SMOC2 | c.676G>A p.E226K (on ENST00000356284 / NM_001166412.2; = p.E237K on NM_022138.3) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs765211821, COSV62445238; called by muse, mutect2, varscan2
- SMTNL2 | c.931G>A p.E311K (on ENST00000389313 / NM_001114974.2; = p.E167K on NM_198501.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV58810224; called by muse, mutect2, varscan2
- SNTG2 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57999399; called by muse, mutect2, varscan2
- SOBP | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs764045698, COSV58003572; called by muse, mutect2, varscan2
- SORCS3 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs1407463397, COSV63799255; called by muse, mutect2, varscan2
- SOX17 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.09); catalogued as COSV52028652; called by muse, mutect2, varscan2
- SP4 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026945; called by muse, mutect2, varscan2
- SPATA21 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV59189038; called by muse, mutect2, varscan2
- SPEG | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV56663892; called by muse, mutect2, varscan2
- SPHKAP | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219251604, COSV100763910; called by muse, mutect2, varscan2
- SPHKAP | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1416078052, COSV100763912; called by muse, mutect2, varscan2
- SPOCD1 | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as COSV57100621; called by muse, mutect2, varscan2
- SPRR1A | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV61081726; called by muse, varscan2
- SPTB | c.6343C>T p.P2115S | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1212051430, COSV61551847; called by muse, mutect2, varscan2
- SRD5A1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs903285160, COSV57012782; called by muse, mutect2, varscan2
- ST18 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52512167; called by muse, mutect2
- STAT1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100738539; called by muse, mutect2, varscan2
- STBD1 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52954613; called by muse, mutect2, varscan2
- STOX2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV57857232; called by muse, mutect2, varscan2
- SULT1C3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV61252394; called by muse, mutect2, varscan2
- SUPT20HL1 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1181704791; called by muse, mutect2
- SYNE1 | c.13591G>A p.E4531K (on ENST00000367255 / NM_182961.4; = p.E4460K on NM_033071.3) | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361139276, COSV55122283; called by muse, mutect2, varscan2
- SYNJ2 | c.3389C>T p.S1130F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); catalogued as COSV62901287; called by muse, mutect2, varscan2
- SYT12 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV67355219; called by muse, mutect2, varscan2
- SYT12 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV101210854; called by muse, mutect2, varscan2
- SZT2 | c.9122A>T p.H3041L (on ENST00000634258 / NM_001365999.1; = p.H2984L on NM_015284.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100981245; called by muse, mutect2, varscan2
- TAAR6 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV51585077; called by muse, mutect2, varscan2
- TACR3 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59209630; called by muse, mutect2, varscan2
- TAF1L | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99644384; called by muse, mutect2, varscan2
- TAF1L | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644386; called by muse, mutect2, varscan2
- TAF4 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV53344019; called by muse, mutect2, varscan2
- TBC1D9 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101121624; called by muse, mutect2, varscan2
- TCHH | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.811); catalogued as rs1483068514, COSV100914949; called by muse, mutect2, varscan2
- TCP11 | c.1187G>A p.G396D (on ENST00000512012; = p.G334D on NM_018679.5) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as rs1421955552, COSV55132072; called by muse, mutect2, varscan2
- TCTN2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs747637823, COSV57633911; called by muse, mutect2, varscan2
- TDRD9 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59157612; called by muse, mutect2, varscan2
- TECTB | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65596738; called by muse, mutect2, varscan2
- TENM4 | c.6661G>A p.G2221R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1167555188, COSV53676811; called by muse, mutect2, varscan2
- TENT4A | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV50103170; called by muse, mutect2, varscan2
- TFR2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as COSV50518691; called by muse, mutect2
- TFR2 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99355504; called by muse, mutect2
- TGM4 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV56094328; called by mutect2, varscan2
- THSD7B | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs375482277; called by muse, mutect2
- TICRR | c.5001G>A p.W1667* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV51547935; called by muse, mutect2, varscan2
- TINAGL1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54700208, COSV99593127; called by muse, mutect2
- TJP1 | c.5230C>T p.L1744F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62045441; called by muse, mutect2, varscan2
- TLL1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286728; called by muse, mutect2, varscan2
- TLL1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99286731; called by muse, mutect2, varscan2
- TLL1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.345); catalogued as COSV50285483, COSV50310001; called by muse, mutect2, varscan2
- TLN2 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60896827; called by muse, mutect2, varscan2
- TLR8 | c.1453G>A p.A485T (on ENST00000218032 / NM_138636.5; = p.A503T on NM_016610.4) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.485); catalogued as COSV54321371; called by muse, mutect2, varscan2
- TMEM192 | c.287T>G p.I96R | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60586496; called by muse, mutect2, varscan2
- TMPRSS15 | c.2388G>A p.W796* | Nonsense Mutation (SNP) | VAF 43/89 reads (48%) | catalogued as rs975406724, COSV53050656; called by muse, mutect2, varscan2
- TMPRSS3 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV52306231; called by muse, mutect2, varscan2
- TNRC6B | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57309503; called by muse, mutect2, varscan2
- TOX2 | c.946A>G p.N316D (on ENST00000358131 / NM_001098798.2; = p.N292D on NM_032883.3) | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57897082; called by muse, mutect2, varscan2
- TP53BP1 | c.1999A>T p.I667F | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV55511061; called by muse, mutect2, varscan2
- TP53BP2 | c.1241C>T p.P414L (on ENST00000343537 / NM_001031685.3; = p.P285L on NM_005426.2) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59073698; called by muse, mutect2, varscan2
- TPO | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV61112589; called by muse, mutect2, varscan2
- TPRA1 | c.123C>T p.S41= | Splice Region (SNP) | VAF 25/71 reads (35%) | catalogued as COSV56162105; called by muse, mutect2, varscan2
- TRANK1 | c.6739G>A p.E2247K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100083056, COSV57166263, COSV57166300; called by muse, mutect2, varscan2
- TRANK1 | c.6521C>T p.A2174V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV57166283; called by muse, mutect2, varscan2
- TRHDE | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs760900602, COSV53834136, COSV99671671; called by muse, mutect2, varscan2
- TRIM3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1564965160, COSV61985936; called by muse, mutect2, varscan2
- TRIM42 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV53887463; called by muse, mutect2, varscan2
- TRIM55 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs140278864; called by muse, mutect2, varscan2
- TRIP11 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as COSV50969767, COSV99970258; called by muse, mutect2, varscan2
- TRPC3 | c.628C>T p.P210S (on ENST00000379645 / NM_001366479.2; = p.P137S on NM_003305.2) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV53382563; called by muse, mutect2, varscan2
- TRPM7 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57922425; called by muse, mutect2, varscan2
- TSPOAP1 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99270587; called by muse, mutect2, varscan2
- TUBA3C | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 326/353 reads (92%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV67139433; called by muse, mutect2, varscan2
- TXNL4A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54100456; called by muse, mutect2, varscan2
- UBE3B | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.405); catalogued as COSV55091077; called by muse, mutect2, varscan2
- UBE3D | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs898739302, COSV52757038; called by muse, mutect2, varscan2
- UGT2A1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54138837, COSV54147273; called by muse, mutect2, varscan2
- UNC79 | c.4606G>A p.A1536T (on ENST00000393151 / NM_001346218.2; = p.A1359T on NM_020818.5) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.275); catalogued as COSV56415474; called by muse, mutect2, varscan2
- UQCRFS1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1568344726, COSV59185546; called by muse, mutect2, varscan2
- URB2 | c.4416G>T p.E1472D | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV51059962; called by muse, mutect2, varscan2
- UROC1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV52040122; called by muse, mutect2
- USP24 | c.3428C>T p.S1143F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs780990315, COSV53777984; called by muse, mutect2, varscan2
- USP29 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54140131; called by muse, mutect2, varscan2
- USP29 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142223; called by muse, mutect2, varscan2
- VAV1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as COSV58392514; called by muse, mutect2, varscan2
- VEGFD | c.686A>C p.D229A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52911387; called by muse, mutect2, varscan2
- VNN3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.582); catalogued as rs865830582, COSV99258159; called by muse, mutect2, varscan2
- VPS13A | c.7313C>T p.S2438F | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.61); PolyPhen benign (0.387); catalogued as COSV62440475; called by muse, mutect2, varscan2
- VPS13B | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100661441; called by muse, mutect2, varscan2
- VPS33A | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV57359153; called by muse, mutect2, varscan2
- VPS37B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1253091003, COSV53445425; called by muse, mutect2, varscan2
- VWA3B | c.2079G>C p.K693N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV68247353; called by muse, mutect2, varscan2
- VWA7 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 38/57 reads (67%) | catalogued as rs138415590, COSV65174258; called by muse, mutect2, varscan2
- VWF | c.5797C>T p.P1933S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs372572865; called by muse, mutect2, varscan2
- WDR12 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53688066; called by muse, mutect2, varscan2
- WDR49 | c.877C>G p.P293A (on ENST00000308378 / NM_001366158.1; = p.P634A on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as COSV57719160; called by muse, mutect2, varscan2
- WDR86 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57842586, COSV57844107; called by muse, mutect2, varscan2
- WNK2 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781468852, COSV52951795; called by muse, mutect2, varscan2
- WTIP | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54330843; called by muse, mutect2, varscan2
- XRN1 | c.3290C>T p.P1097L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53819144; called by muse, mutect2, varscan2
- XRN1 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV53819153; called by muse, mutect2, varscan2
- ZBBX | c.2114T>G p.L705* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV56803214; called by muse, mutect2, varscan2
- ZBTB16 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.039); catalogued as rs1368436455, COSV60093163, COSV60100543; called by muse, mutect2, varscan2
- ZDBF2 | c.1332A>T p.K444N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65630685; called by muse, mutect2, varscan2
- ZDHHC17 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs781688820, COSV58351376; called by muse, mutect2, varscan2
- ZEB1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV58056580; called by muse, mutect2, varscan2
- ZFP14 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV54205414; called by muse, mutect2, varscan2
- ZFP64 | c.1724A>C p.E575A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99402179; called by muse, mutect2, varscan2
- ZFP64 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs767182744, COSV99402181, COSV99402659; called by muse, mutect2, varscan2
- ZFYVE19 | c.985C>G p.L329V (on ENST00000355341 / NM_001077268.2; = p.L319V on NM_032850.5) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as COSV54542406; called by muse, mutect2, varscan2
- ZIK1 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56738721; called by muse, mutect2, varscan2
- ZIM2 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55650086; called by muse, mutect2, varscan2
- ZNF101 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58909087; called by muse, mutect2, varscan2
- ZNF157 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65659453; called by muse, mutect2, varscan2
- ZNF260 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV72951303; called by muse, mutect2, varscan2
- ZNF318 | c.6773G>A p.G2258E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58938408; called by muse, mutect2, varscan2
- ZNF384 | c.1649C>T p.P550L (on ENST00000361959; = p.P489L on NM_133476.5) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs926328401, COSV100158314; called by muse, mutect2, varscan2
- ZNF384 | c.1648C>T p.P550S (on ENST00000361959; = p.P489S on NM_133476.5) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs937678632, COSV58555955; called by muse, mutect2, varscan2
- ZNF43 | c.1376G>T p.C459F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100731970, COSV61686332; called by muse, mutect2, varscan2
- ZNF510 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 37/52 reads (71%) | catalogued as COSV56298368, COSV56299388; called by muse, mutect2, varscan2
- ZNF585A | c.850C>T p.H284Y (on ENST00000292841 / NM_001288800.2; = p.H229Y on NM_152655.3) | Missense Mutation (SNP) | VAF 118/197 reads (60%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.609); catalogued as COSV53067584; called by muse, mutect2, varscan2
- ZNF683 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV62876097; called by muse, mutect2, varscan2
- ZNF766 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63010406; called by muse, mutect2, varscan2
- ZSCAN21 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52852744; called by muse, mutect2, varscan2
- ZSCAN5B | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV62841152; called by muse, mutect2
- CD63 | c.257_258dup p.A87Lfs*26 | Frame Shift Ins (INS) | VAF 34/119 reads (29%) | called by mutect2, pindel, varscan2
- CSPG4 | c.3205_3209dup p.V1071Wfs*3 | Frame Shift Ins (INS) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.1271_1275del p.F424Cfs*3 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- GP1BA | c.1461_1462del p.L488Rfs*9 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by pindel, varscan2
- HNRNPR | c.1417_1428del p.D473_G476del | In Frame Del (DEL) | VAF 43/122 reads (35%) | called by mutect2, pindel, varscan2
- IGHG2 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PGBD2 | c.491_492del p.Y164Cfs*50 | Frame Shift Del (DEL) | VAF 40/103 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PRAMEF19 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2
- PRAMEF19 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRAMEF7 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RIMBP3 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by mutect2, varscan2
- ZNF488 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC1 | c.1344C>T p.P448= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs770162860, COSV100579067; called by muse, mutect2, varscan2
- ABCC1 | c.4413C>T p.T1471= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs765042675, COSV100579070; called by muse, mutect2, varscan2
- ABTB1 | c.870C>T p.F290= (on ENST00000232744 / NM_172027.3; = p.F148= on NM_032548.3) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV51743020; called by muse, mutect2, varscan2
- ACSF2 | c.1254C>T p.F418= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs769485871, COSV51974475; called by muse, mutect2, varscan2
- ADAM28 | c.1485C>T p.F495= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56106350; called by muse, mutect2, varscan2
- ADAMDEC1 | c.435G>A p.G145= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV56477958; called by muse, mutect2, varscan2
- ADAMDEC1 | c.892C>T p.L298= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1470517748, COSV56477963, COSV99835811; called by muse, mutect2, varscan2
- ADAMTS6 | c.1329C>T p.S443= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV101125284, COSV66865427; called by muse, mutect2, varscan2
- ADGRA3 | c.1923C>T p.F641= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV51569278; called by muse, mutect2, varscan2
- ADIPOQ | c.63G>A p.T21= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs200633565; called by muse, mutect2, varscan2
- AGAP3 | c.1761T>C p.A587= (on ENST00000622464; = p.A623= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV68247071; called by muse, mutect2, varscan2
- AHNAK | c.5457T>C p.G1819= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV57233870; called by muse, mutect2, varscan2
- AKAP4 | c.1336C>T p.L446= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV62075718; called by muse, mutect2, varscan2
- AL592490.1 | c.1926G>A p.K642= | Silent (SNP) | VAF 60/71 reads (85%) | catalogued as rs144379684; called by muse, mutect2, varscan2
- ALPK3 | c.588C>T p.I196= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV51941110; called by muse, mutect2, varscan2
- ALX4 | c.660C>T p.T220= | Silent (SNP) | VAF 66/151 reads (44%) | catalogued as COSV61329423; called by muse, varscan2
- AMOTL2 | c.399C>T p.P133= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1229317536, COSV51441293; called by muse, mutect2, varscan2
- AMTN | c.381C>T p.I127= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV59490433; called by muse, mutect2, varscan2
- ANGPTL8 | c.228C>T p.L76= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV52949830; called by muse, mutect2
- ANK1 | c.1020C>T p.T340= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV55897995; called by muse, mutect2, varscan2
- ANK3 | c.9264G>A p.E3088= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV55085665; called by muse, mutect2
- ANKRD50 | c.1173C>T p.I391= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as COSV72386401; called by muse, mutect2, varscan2
- ANO2 | c.1533G>A p.T511= (on ENST00000356134 / NM_001278597.3; = p.T515= on NM_001278596.3) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs766273034, COSV59033427, COSV59046266; called by muse, mutect2, varscan2
- ANO5 | c.822C>T p.H274= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV61090962; called by muse, mutect2, varscan2
- APLNR | c.519G>A p.L173= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57244236; called by muse, mutect2, varscan2
- AQP1 | c.645G>A p.G215= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1444358457, COSV61266194; called by muse, mutect2, varscan2
- AQP6 | c.432G>A p.A144= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs773633463, COSV100210330, COSV59646598; called by muse, mutect2, varscan2
- AQP8 | c.405G>A p.E135= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV54847822; called by muse, mutect2, varscan2
- AREG | c.372C>T p.P124= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ARID4A | c.57G>A p.K19= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs776110314, COSV62167011; called by muse, mutect2, varscan2
- ARMC4 | c.1374G>A p.V458= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV53463661; called by muse, mutect2, varscan2
- ARMH4 | c.2061C>T p.L687= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs111628716, COSV50776489; called by muse, mutect2
- ARPP21 | c.531C>T p.F177= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV51793939; called by muse, mutect2, varscan2
- ASPM | c.6813G>A p.R2271= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV54125377; called by muse, mutect2, varscan2
- ATP10B | c.2310G>A p.R770= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1193986649, COSV59166289; called by muse, mutect2, varscan2
- ATP2B3 | c.465C>T p.I155= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as rs782813423, COSV54861599; called by muse, mutect2, varscan2
- ATR | c.5410C>T p.L1804= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV63393553; called by muse, mutect2, varscan2
- AXL | c.2259G>A p.V753= (on ENST00000301178 / NM_021913.5; = p.V744= on NM_001699.6) | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV56575918; called by muse, mutect2, varscan2
- BMP10 | c.762C>T p.I254= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs764620390, COSV54895993; called by muse, mutect2, varscan2
- BMP8A | c.300C>T p.G100= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV59034604; called by muse, mutect2, varscan2
- BPIFB1 | c.742C>T p.L248= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV53609216; called by muse, mutect2, varscan2
- BRPF3 | c.888C>T p.I296= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV60206745; called by muse, mutect2, varscan2
- C3 | c.4323G>A p.R1441= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as COSV55573183; called by muse, mutect2, varscan2
- C8B | c.648G>A p.V216= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV64777753; called by muse, mutect2, varscan2
- C9 | c.1320G>A p.L440= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54682235; called by muse, mutect2, varscan2
- CACNA1E | c.2916G>A p.T972= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs771250828, COSV62396455; called by muse, mutect2, varscan2
- CACNG5 | c.705C>T p.D235= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs376605267; called by muse, mutect2, varscan2
- CARD8 | c.765C>T p.S255= (on ENST00000651546 / NM_001184900.3; = p.S205= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV62874472; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>A p.Q513= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD1B | c.423C>T p.F141= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as COSV63803828; called by muse, mutect2, varscan2
- CD3G | c.369C>T p.I123= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs769843997, COSV52675530, COSV99416684; called by muse, mutect2, varscan2
- CDC27 | c.1116C>T p.N372= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs76836956, COSV50418214; called by muse, mutect2, varscan2
- CDYL2 | c.336C>T p.P112= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV73647574, COSV73647629, COSV73647820; called by muse, mutect2, varscan2
- CELF4 | c.669C>T p.S223= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV58467947; called by muse, mutect2, varscan2
- CGNL1 | c.2043G>A p.K681= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1567127232, COSV55576563; called by muse, mutect2, varscan2
- CIDEB | c.63G>A p.S21= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs780852667, COSV51865480, COSV99350837; called by muse, mutect2, varscan2
- CLDN9 | c.465C>T p.A155= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100172105; called by muse, mutect2, varscan2
- COL11A2 | c.2688C>T p.P896= (on ENST00000341947 / NM_080680.3; = p.P789= on NM_080679.2) | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1025838453, COSV59503431; called by muse, mutect2, varscan2
- COL6A1 | c.1374C>T p.G458= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100720068; called by muse, mutect2
- CR2 | c.621C>T p.P207= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs573346582, COSV100889572, COSV100889648; called by muse, mutect2, varscan2
- CSF1R | c.1978C>T p.L660= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53844501; called by muse, mutect2, varscan2
- CSF2RB | c.2001C>T p.S667= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV99453544; called by muse, mutect2, varscan2
- CTSE | c.870C>T p.S290= (on ENST00000360218; = p.S285= on NM_001910.4) | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100733571; called by muse, mutect2, varscan2
- CYBA | c.240C>T p.F80= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as rs373948664, COSV99879954; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP2W1 | c.744G>A p.L248= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV58271771; called by muse, mutect2, varscan2
- DCSTAMP | c.891C>T p.F297= | Silent (SNP) | VAF 58/210 reads (28%) | catalogued as COSV52580220; called by muse, mutect2, varscan2
- DHCR7 | c.786C>T p.L262= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV62795534; called by muse, mutect2, varscan2
- DIDO1 | c.558T>C p.S186= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV56635396; called by muse, mutect2, varscan2
- DIP2C | c.1335C>T p.C445= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1220855425, COSV55181935; called by muse, mutect2, varscan2
- DNAH3 | c.7740C>T p.F2580= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1446054977, COSV54557046; called by muse, mutect2, varscan2
- DNAH8 | c.13278C>T p.F4426= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV59484962; called by muse, mutect2, varscan2
- DNAH9 | c.6219C>T p.S2073= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52380456; called by muse, mutect2, varscan2
- DNER | c.816G>A p.E272= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV59178370; called by muse, mutect2, varscan2
- DNMT3B | c.2280G>A p.L760= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52424563; called by muse, mutect2, varscan2
- DPP10 | c.1218C>T p.I406= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV59737252; called by muse, mutect2, varscan2
- DRG2 | c.384C>T p.G128= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV56729644; called by muse, mutect2
- DSC1 | c.267G>A p.R89= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV57143423; called by muse, mutect2, varscan2
- DTNB | c.186C>T p.F62= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs1383202375, COSV56485691; called by muse, mutect2, varscan2
- EGR4 | c.1518C>T p.I506= (on ENST00000545030; = p.I403= on NM_001965.4) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV71532342; called by muse, mutect2, varscan2
- ELFN2 | c.2139C>T p.P713= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs764038571, COSV101297518; called by muse, varscan2
- EMILIN2 | c.387C>T p.L129= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99598337, COSV99599088; called by muse, mutect2, varscan2
- EPHA6 | c.3000C>T p.H1000= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs761026433, COSV67596485; called by muse, mutect2, varscan2
- EPHA7 | c.741G>A p.R247= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV65170705; called by muse, mutect2, varscan2
- ERMARD | c.1107A>G p.R369= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV64648956; called by muse, mutect2, varscan2
- EXOC8 | c.1197C>T p.S399= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99149612; called by muse, mutect2, varscan2
- EXT1 | c.1440C>T p.F480= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs200294824, COSV65485813; called by muse, mutect2, varscan2
- FAT4 | c.8481G>A p.G2827= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1440397362, COSV58712242; called by muse, mutect2, varscan2
- FBXO22 | c.993T>C p.F331= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV57619279; called by muse, mutect2, varscan2
- FHDC1 | c.2394G>A p.P798= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs764837988, COSV52603836; called by muse, mutect2, varscan2
- FILIP1L | c.1203G>A p.K401= (on ENST00000354552 / NM_182909.3; = p.K161= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as COSV58777200; called by muse, mutect2, varscan2
- FUT5 | c.945G>A p.L315= | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2
- FUT6 | c.789C>T p.A263= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as COSV99744438; called by muse, mutect2, varscan2
- FUT8 | c.1353C>T p.I451= (on ENST00000360689 / NM_001371534.1; = p.I288= on NM_004480.4) | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV61292165; called by muse, mutect2, varscan2
- GAB1 | c.1266C>T p.G422= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53761550; called by muse, mutect2, varscan2
- GABPA | c.219C>T p.I73= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs1282810844, COSV61395833; called by muse, mutect2
- GABRB1 | c.993C>T p.F331= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54991663, COSV55002253; called by muse, mutect2, varscan2
- GANAB | c.2760C>T p.D920= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55490777; called by muse, mutect2, varscan2
- GAS2L2 | c.936C>T p.S312= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- GFRAL | c.882G>A p.R294= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV61236299; called by muse, mutect2, varscan2
- GGTLC2 | c.555C>T p.I185= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1203107042; called by mutect2, varscan2
- GMPPA | c.306C>T p.I102= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV58008825; called by muse, mutect2, varscan2
- GP1BA | c.1530G>A p.G510= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV56701044; called by muse, varscan2
220 further variants in this file (0 protein-altering or splice-affecting, 195 silent, 25 other) are not listed here.
